Surgical pathology report (de-identified scan), TCGA case TCGA-XU-A92R, project TCGA-THYM (Thymoma), tissue source site University Health Network, specimen TCGA-XU-A92R-01A (Primary Tumor).

[page 1 of 4]
Patient Name:

MRN:

DOB:

Gender:F

Age:

Service:

Visit #:

Location:

Facility:

Collected:

Resulted:

Ordering MD:

Surgical Pathology Consultation Report

SPECIMEN(S) RECEIVED

1. Thymus: short single-R upper pole/short dble-L upper pole/long single-anterior/long dble-posterior
2. Soft Tissue: Left Hilar Metastatic Deposit

ICD-O-3

Thymoma, type AB
malignant 8582/3

DIAGNOSIS

Site: Thymus C379
9/2 4/2/14

1. Thymus, resection:

- a) Thymoma, WHO type AB (mixed type), with: (see Comment)

- i) Greatest tumour dimension = 5.0 cm
- ii) Focal microscopic invasion of mediastinal fat
- iii) Tumour present within 0.1 cm of painted, cauterized

surface of specimen

- iv) Focal increased atypia and clear cell change, of uncertain significance

- b) Uninvolved thymic tissue with involutional changes and a single focus of microscopic thymoma

2. Soft tissue, resection ("left hilar metastatic deposit"):

- Consistent with metastatic thymoma (see Comment), completely excised
- Minimal surrounding thymic tissue with involutional changes

SYNOPTIC DATA

Specimen Type:

Not specified

Specimen Size:

Greatest dimension: 11.8 cm

Additional dimensions: 7.5 x 3.0 cm

Tumor Site:

Thymus

Tumor Size:

Greatest dimension: 5.0 cm

Additional dimensions: 2.8 x 5.0 cm

Histologic Type:

Type AB thymoma (mixed)

Pathologic Staging:

Stage IVb: Hematogenous or lymphatic

Status: complete

Page: 1 of 4

[page 2 of 4]
Patient Name:

MRN:

DOB:

Gender: F

Service:

Visit #:

Location:

Facility:

Collected:

Resulted:

Ordering MD:

dissemination

Regional Lymph Nodes:

pNX: Cannot be assessed

Distant Metastasis:

Cannot be assessed

Margins:

Margins uninvolved by tumor

Distance of tumor from closest

margin: 1 mm

Invasion of Pulmonary Parenchyma: Absent

Pleural Invasion: Absent

Vascular (Small/Large Vessel) Invasion: Absent

Additional Pathologic Findings: focal increased atypia and clear

cell change, microscopic thymoma in adjacent thymus tissue

COMMENT

1. Sections show thymic tissue with an encapsulated mass composed predominantly of uniform oval to spindle cells with bland nuclear features. The cells are arranged in sheets, and neither lobulations nor broad fibrous septae are dominant features. There are few scattered lymphocytes. These areas have the histologic features of a WHO type A thymoma. One area of the tumour shows different morphologic features, with more abundant lymphocytes and epithelial cells with small, central nucleoli, consistent with WHO type B2 pattern. The tumour overall is therefore best classified as WHO type AB. The morphology is similar to that of the previous biopsy of this lesion. The tumour focally invades into the surrounding mediastinal fat. A small portion of lung tissue is adherent to the tumor, but there is no invasion of the lung by tumor. Tumour is present within 0.1 cm of a painted, cauterized surface of specimen. However, the tumour is encapsulated in this area, which most likely represents the anterior surface of the tumour (point of contact with chest wall). The resection margins are otherwise negative for tumour.

A single focus within the tumour is noted that shows increased cellular atypia and clear cell change. These cells are positive for low-molecular weight keratin by immunohistochemistry, consistent with epithelial cells, but their significance is unclear. Close follow-up is recommended.

The adjacent uninvolved thymic tissue shows involutional change. A single focus of so-called microscopic thymoma (< 0.1 cm diameter) is noted close

[page 3 of 4]
Patient Name:

MRN: .
DOB: (Age: .
Gender: F

Service:
Visit #:
Location:
Facility:

Collected:
Resulted: .

Ordering MD:

to the superior pole resection margin (distance = 0.5 cm).

2. Sections show a nodule of tumour with similar morphologic features to that seen in the main thymoma specimen. The nodule is well circumscribed and completely surrounded by a rim of soft tissue that appears to include a small portion of residual non-neoplastic thymic tissue. Assuming this nodule to be separate from the main tumour, the features are consistent with a metastatic deposit, but it is uncertain based on the histology whether this represents a soft tissue or lymph node metastasis. Correlation with clinical and radiologic findings is needed.

ELECTRONICALLY VERIFIED BY

CLINICAL HISTORY

Thymoma

GROSS DESCRIPTION

1. The specimen labeled with the patient's name and as "thymus: Short single-R upper pole/short dble-L. upper pole/long single-anterior/long dble-posterior", consists of an 11.8 cm SI x 7.5 cm ML x 3.0 cm AP thymus gland, received fresh. There is a 5.0 cm SI x 2.8 cm AP x 5.0 cm ML tan, homogenous, lobulated tumor within the specimen, with gross resection margins of anterior 0.1 cm, posterior 0.1 cm, right superior pole 7.0 cm, left superior pole 4.7 cm, inferior 0.2 cm, right lateral 3.0 cm and left lateral 0.4 cm. The remaining thymus gland is fatty and unremarkable. Surgical margins are painted with silver nitrate; the anterior surface is over coated with green dye and the right posterior surface with India ink. The tumor and normal thymus gland are sampled for tissue banking. Representative sections are submitted as follows:
1A-1C full-thickness anterior-posterior sections of tumor sampled from right-left, with margins, 1A-1B a bisected section
1D tumor, with inferior margin
1E tumor, with adjacent superior thymus tissue
1F right pole superior margin
1G left pole superior margin
1H right lateral margin
1I tumor, with left lateral margin
1J-1K tumor
1L-1M grossly unremarkable thymus, sampled superior to the tumor

Status: complete

Page: 3 of 4

[page 4 of 4]
Patient Name:

MRN:

DOB: (Age:

Gender:F

Ordering MD:

Service:

Visit #:

Location:

Facility:

Collected:

Resulted:

2. The specimen labeled with the patient's name and as "soft tissue: Left hilar metastatic deposit", consists of a 1.2 x 0.8 x 0.4 cm oval piece of tan homogenous tissue, received in 10% buffered formalin.
2A bisected and submitted in toto

Status: complete

Page: 4 of 4

Source: NCI Genomic Data Commons file b5c3b3e1-91bb-4577-909c-98e1a3b18e67 (TCGA-XU-A92R.0B9113FE-BCED-427C-867C-15CB1623A162.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).